Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8563, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8563-01A (Primary Tumor).

Pathology Report for Subject: [REDACTED]

Addendum Diagnosis:

Anaplastic Astrocytoma, gemistocytic

MIB-1 labeling index = 2.0%

Microscopic Description:

Sections demonstrate diffusely infiltrative moderately hypercellular astrocytic neoplasm. In most areas there is a marked preponderance of gemistocytes. Atypia is generally moderate and many scattered markedly atypical cells are seen. However, an extensive examination does not demonstrate mitoses. There is no microvascular proliferation or necrosis.

Source: NCI Genomic Data Commons file 91f429b1-8d3d-4a35-bd5f-1d319bf18046 (TCGA-HT-8563.5A5EA09F-FBC2-43A7-A135-7DB5B681AE76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).